Surgical pathology report (de-identified scan), TCGA case TCGA-24-1927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1927-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-1927

SURGICAL PATHOLOGY REPORT

Other Related Clinical Data:

DIAGNOSIS: SPECIMEN LABELED "BILATERAL OVARIES," EXCISION

- ADENOCARCINOMA, MIXED SEROUS \T\ ENDOMETRIOID TYPE, INVOLVING OVARIAN AND PERITUBAL TISSUE

OMENTUM, OMENTECTOMY

- ADENOCARCINOMA, MIXED SEROUS \T\ ENDOMETRIOID TYPE

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pick up 'bilateral ovaries,' consisting of a 103 gram, 10.5 x 6.2 x 2.9 cm adhered mass of tissue containing soft, gray tumor, much of which appears to stud the peritoneal surface. Portion frozen as FS1. There is no discernible ovarian architecture," by

FS1: Ovary biopsy

- "Adenocarcinoma, consistent with Mullerian derivation," by

Microscopic Description and Comment: Histologic sections from the specimen labelled "bilateral ovaries" show extensive poorly-differentiated adenocarcinoma of mixed serous and endometrioid type with serous carcinoma predominating. Adenocarcinoma involves remnants of ovary which are identified by the presence of corpora albicantia. Also identified are two fallopian tubes. The adenocarcinoma is present in peritubal soft

[page 2 of 4]
[REDACTED]

tissue. The omentum is nearly completely replaced by identical-appearing mixed serous and endometrioid adenocarcinoma. [REDACTED]

History: The patient is a [REDACTED] with a pelvic mass. Operative procedure:
Exploratory laparotomy with biopsy and bilateral salpingo-oophorectomy.

Specimen(s) Received:

A: BILATERAL OVARIES

B: OMENTUM BIOPSY

Gross Description The specimens are received in two formalin-filled containers, each labeled with the patient's name. The first container is labeled "bilateral ovaries, FS1." It contains a white cassette labeled "FS1" which holds a fragment of tan-white, friable tissue measuring 2 x 1 x 0.2 cm, consistent with the frozen section remnant. Labeled A1 (FS1). Also within the container is a fragment of severely adhered tissue with yellow-tan and friable tumor, with measurements and description matching those in the intraoperative consultation.

One area has been previously cut open, consistent with the previous frozen section site. However, some other areas also show the tumor present on the surface. Two fimbriated ends of fallopian tube are identified, each with attached segment of fallopian tube measuring 3 cm in length and 0.5 cm in diameter. Both fallopian tubes are encased by the tumor. No discernible ovarian architecture is identified. Labeled A2 to A7 - random section of the tumor; A8 \T\ A9 - random section of the tumor and adjacent fallopian tubes. Jar 2.

The second container is labeled "omentum biopsy." It contains an adhered, brown-yellow omentum with a firm, tan-white tumor measuring 10 x 10 x 2 cm. The omentum is almost entirely replaced by white, tan, firm tumor. Labeled B1 to B3 - random section of the omentum with tumor. Jar 3.

[REDACTED]

Synopsis SYNOPSIS REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1.
PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is:

Other (MIXED SEROUS AND ENDOMETRIOID)

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary (synchronous primary tumors)

5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)

6. Tumor IS identified on the ovarian surface(s).

7 Tumor DOES invade the mesovarium.

8. Tumor DOES invade the adjacent paratubal soft tissue

9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.

10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.

11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.

12. Metastatic involvement of the omentum is PRESENT.

[page 3 of 4]
13. The maximum dimension of tumor implants outside the true pelvis is 10 cm
14. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.
15. Metastatic involvement of the endometrium CANNOT BE EVALUATED.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0
18. The total number of metastatically-involved regional lymph nodes is Not evaluable
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
3c	IIIC	peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver	

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file c5a0703f-5f7b-48f0-8856-76318cd66987 (TCGA-24-1927.67121EF6-223F-47B5-8094-81FFFFCC6951.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).